Somatic mutation profile of tumor specimen 0DFF73 from CCDI case PBBRUS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 2.6 years (956 days).
Specimen 0DFF73: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 507a918b-a1ca-49bf-84ba-4a5b1e9e281d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFF70 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/433cc811-5785-4055-9097-145a9d434b7d

The open-access MAF lists 2 somatic variants for this specimen: 2 silent.
By variant classification: Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH4 | c.1314C>T p.S438= | Silent (SNP) | VAF 55/474 reads (12%) | catalogued as rs372927032; called by muse, mutect2, varscan2
- ZNF90 | c.540A>G p.K180= | Silent (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2
